RC case RC-B5DP — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7ed2be23-b7e2-4097-8725-ca97c24fb0c3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1951; Vital status: Alive.

Diagnoses (2)
1. T-cell large granular lymphocytic leukemia (the primary disease): ICD-O-3 morphology code: 9831/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 66.1 years (24,146 days); Year of diagnosis: 2017; Method of diagnosis: Bone Marrow Aspirate; Ann Arbor B symptoms: No; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Bone marrow / Peripheral blood.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate; Initial disease status: Initial Diagnosis; Days to treatment start: 2 days; Days to treatment end: 124 days; Treatment outcome: Stable Disease; Reason treatment ended: Other; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate; Initial disease status: Initial Diagnosis; Days to treatment start: 613 days (1.7 years); Days to treatment end: 815 days (2.2 years); Treatment outcome: Stable Disease; Reason treatment ended: Other; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Ruxolitinib; Initial disease status: Initial Diagnosis; Days to treatment start: 831 days (2.3 years); Treatment outcome: Treatment Ongoing; Clinical trial indicator: Yes; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Stable Disease; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Prior malignancy of the prostate gland (histology not recorded by GDC). Age at diagnosis: 59.9 years (21,866 days); Year of diagnosis: 2011; Days to diagnosis: -2,280 days (-6.2 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -2,280 days (-6.2 years); Treatment anatomic sites: Prostate.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 100.
- Day 1,447 (end of treatment course 1): Disease response: With Tumor.
- Days to follow up: 1,727 days (4.7 years); Disease response: With Tumor.

Molecular and laboratory tests
- Lactate Dehydrogenase 258 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Osteoporosis or Osteopenia.
- Timepoint category: Follow-up; Comorbidities: Osteoporosis or Osteopenia / Cataracts.
- Timepoint category: Initial Diagnosis; Weight: 112.1 kg; Height: 185 cm; BMI: 32.8.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B5DP-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample RC-B5DP-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
  Slide RC-B5DP-TBP1-A-1-0-CS2: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 80; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 10.
